Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A27F, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A27F-01A (Primary Tumor).

ICD-0-3
Carcinoma, infiltrating duct, NOS 8500/3
Site: breast, NOS C50.9 for 5/19/11

page 1 / 1

copy No. 7

Date:

Examination: Histopathological examination

Internal invoice No.

Value of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: Multiple organ resection – right breast with axillary tissues

Unit in charge:

Physician in charge: prof.

N/A

Material collected on:

Material received on:

Expected time of examination: up to 8 working days

Clinical diagnosis: Cancer of the right breast. †

IHPAA Discrepancy		
Case # (electronic)		
Review of quality		

Examination performed on:

Results of immunohistochemical examination:

No estrogen receptors found in the neoplastic cell nuclei. No progesterone receptors found in the neoplastic cell nuclei. HER2 protein stained with HercepTest™ by DAKO.
Negative reaction in invasive cancerous cells (Score = 1+)

dr

Compliance validated by: dr

Examination performed on:

Macroscopic description:

Right breast sized 19 x 14 x 4 cm removed along with axillary tissues sized 8 x 7 x 3 cm and a skin flap of 17 x 8 cm. Tumour sized 2.5 x 2.3 x 2.0 cm in the upper outer quadrant, located 1.7 cm from the upper boundary, 0.2 cm from the base and 0.8 cm from the skin.

Microscopic description:

Carcinoma ductale invasivum NHG3 (3+3+3: 24 mitoses/10 HPF - visual area: 0.55mm).

Glandular tissue outside the tumour showing lesions of the type mastopathia fibrosa, adenosis simplex.

Axillary lymph nodes:

Sinus histiocytosis lymphonodorum (No XI).

Histopathological diagnosis:

Carcinoma ductale invasivum mammae dextrae. Invasive ductal carcinoma of the right breast (NHG3, pT2, pNO).

dr

Compliance validated by: dr

Source: NCI Genomic Data Commons file 6b5b0b3e-1c07-4eed-bcf4-1068717b517e (TCGA-D8-A27F.976C6F9E-DDCB-42F4-BD2C-A4D715396B47.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).